Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZN-06A (Metastatic).

[page 1 of 3]
Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: Plastic Surgery Department

Copy To: n/a

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Melanoma.

MACROSCOPIC:

1. Right iliac node: fibroadipose tissue, 7 x 2 x 1.5 cm, containing up to seven lymph nodes, ranging from 0.5 cm to 1 cm.
2. Right obturator node: fatty tissue, 6 x 2.5 x 1 cm, containing two probable lymph nodes, 1 cm and 1.5 cm, and two smaller ? nodes, up to 0.5 cm each.

MICROSCOPY:

1. Right iliac node: seven reactive lymph nodes confirmed. No evidence of metastatic malignant melanoma seen.
2. Right obturator node: four reactive lymph nodes seen with no evidence of metastatic malignant melanoma. Melanophages, however, were confirmed with node parenchyma.

DIAGNOSIS:

1. RIGHT ILIAC NODE: SEVEN REACTIVE LYMPH NODES CONFIRMED.
2. RIGHT OBTURATOR NODE: FOUR REACTIVE LYMPH NODES CONFIRMED.

REPORTED BY:

Dr. Consultant Histopathologist

REPORT DATE:

ICD-O.3
Melanoma NOS 8720/3
Site: Lymph node NOS C72.9
Q40 5/19/14

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

**SUPPLEMENTARY REPORT

LAB No:

Bank No:

CASE HISTORY:

Right groin excision for tissue banking. Please note that other

[page 2 of 3]
lymph nodes will be reported and laboratory number

MACROSCOPIC:

Ellipse 13 x 4 cm with underlying fat 16 x 7 x 3 cm. Near the centre of the specimen is a black nodule 2 cm diameter which extends very close to the deep margin and is visible through the connective tissue covering (A).

MICROSCOPY:

The largest deposit is malignant melanoma which appears to be partly within a lymph node and partly within perinodal connective tissue. It is up to 19 mm diameter. 2 of 10 further lymph nodes also contain small deposit of metastatic melanoma

DIAGNOSIS:

RIGHT GROIN LYMPH NODES: METASTATIC MALIGNANT MELANOMA (3 OF 11)

REPORTED BY:

Dr , Consultant Histopathologist

REPORT DATE:

SUPPLEMENTARY REPORT:

Sequencing analysis of the BRAF gene has revealed NO MUTATION within codon 600 of BRAF gene.

MELANOMA: NO EVIDENCE OF BRAF MUTATION

REPORTED BY:

Dr Consultant Histopathologist

Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT:

Copy to: Dr Consultant Pathologist,

Reported to Cancer Registry

CYTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Review of two slides from specimen taken for

The history from report reads:

Past medical history metastatic malignant melanoma

Specimen

FNA sub-dermal lesion right buttock

MACROSCOPIC:

The macroscopic description from reads:

[page 3 of 3]
Two wet fixed slides received.

MICROSCOPY:

A highly cellular sample containing abundant atypical epithelioid cells, many of which contain pigment. The features support metastatic malignant melanoma and we are in agreement with the report sent from the referring pathologist.

DIAGNOSIS:

FNA, RIGHT BUTTOCK LESION: METASTATIC MALIGNANT MELANOMA

REPORTED BY:

Dr Histopathology
Dr Consultant Histopathologist

REPORT DATE:

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Plastic Surgery

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Metastatic melanoma

MACROSCOPIC:

1. Right lower buttock. Ellipse 2.7 x 1.2 cm with underlying fat to 2.5 cm. The fat has been painted green and contains an incision which reveals a 1 cm dark brown nodule which is 0.4 cm from the incised margin. It is closer to the opposite, non-painted margin.
2. Right upper buttock. 2.5 cm ellipse with underlying fat to 1.5 cm. It contains a 1.2 cm dark brown nodule which extends close to a superficial subcutaneous margin.
3. Deep margin right lower buttock. A fragment.

MICROSCOPY:

1. Metastatic malignant melanoma extending to 1.2 mm of the closest margin (opposite the surgical incision)
2. Metastatic malignant melanoma, 0.7 mm from the closest margin
3. Scarring, mild inflammation and some foreign body giant cells.
- No tumour seen

DIAGNOSIS:

RIGHT LOWER AND RIGHT UPPER BUTTOCK: METASTATIC MALIGNANT MELANOMA

REPORTED BY:

Dr Consultant Histopathologist

REPORT DATE:

Source: NCI Genomic Data Commons file 54bf78a1-beb0-472b-a27e-98d8ff112a32 (TCGA-WE-A8ZN.BE0832E4-B3D5-4193-96CC-F296F99F96E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).